CCDI case PBBVPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/924b6ad9-c589-43e3-b60c-75f2263a114f

Demographics
Sex at birth: male; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 15.2 years (5,534 days).

Biospecimens (3 samples)
- Sample 0DIQZN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR07: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR1P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
